Somatic mutation profile of tumor specimen C3L-06956-55 (aliquot CPT0374940002) from CPTAC case C3L-06956, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.5 years (25,385 days).
Specimen C3L-06956-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2476023-fefa-48ae-954c-02c3a318481b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06956-50 (Buccal Cell Normal), aliquot CPT0375020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/744dcb28-b751-4352-af70-2eae0e0ebfbe

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Frame Shift Ins 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 10/71 reads (14%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SH2D1A | c.239T>G p.I80R | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as CM1010333; called by muse, mutect2
- TET2 | c.5059C>T p.Q1687* | Nonsense Mutation (SNP) | VAF 61/165 reads (37%) | catalogued as rs868010336, COSV54399904; called by muse, mutect2, varscan2
- SETD1A | c.2130C>T p.A710= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1567353733; called by muse, mutect2, varscan2
